Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAQ3, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAQ3-01A (Primary Tumor).

[page 1 of 3]
TSS Patient ID:

Surgical Date:

Gross Description: Received is 1 specimen with pancreatic and duodenal tissue

with several sutures present. The duodenum measures 19 cm in length x 3.2

cm in diameter. The serosal surface is smooth, glistening, tan-pink with

cautery artifact. The duodenum is opened longitudinally to reveal

tan-brown mucosa with an ampulla that is 5 cm from the proximal margin, and

is surrounded by a 1.7 x 1 cm red-tan ulcerative lesion.

The pancreas measures 7.5 x 6 x 4.5 cm, and the neck margin is removed en

face and submitted for frozen section diagnosis. The pancreas is sectioned to reveal that the major pancreatic duct

is obstructed approximately 1.5 cm from the neck margin. There is an

ill-defined, indurated, white-yellow lesion that is 2 x 2.5 x 2.3 cm. The

mass possibly invades the common bile duct, which is friable and

hemorrhagic, and dilated to 1.2 cm in diameter. The common bile duct is

patent through the ampulla. The mass is 1 cm to the neck margin, 0.8 cm to

the long blue (portal vein), 2.8 cm to the long black (SMA), 0.6 to looped

black (deep radial), 0.1 cm to nearest radial margin, and 6 cm to the

proximal duodenal margin.

Microscopic Description:

Diagnosis Details: - Pancreatic ductal adenocarcinoma, moderately differentiated

- AJCC pathologic stage (7th edition): pT3 pN1, stage IIB

Pancreas (Exocrine) Cancer Synopsis Specimens Involved Specimens:

A: Common bile duct FS

B: Metal stent (for identification only)

C: Gastroduodenal artery lymph node

ICD-6-3
Adenocarcinoma, duct NOS 8550/3
Site: Pancreas head 2.25.0
4/25/14

[page 2 of 3]
D: Whipple FSx2

Specimen: Head of pancreas, Duodenum, Common bile duct

Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

Tumor Site: Pancreatic head

Tumor size greatest dimension: 2.5cm

Histologic Type: Ductal adenocarcinoma

Histologic Grade (ductal carcinoma only): G2

Microscopic Tumor Extension: Tumor invades peripancreatic soft tissues

AJCC Stage (7th Edition) (pTNM)

Primary Tumor (pT): pT3

Regional Lymph Nodes (pN): pN1

Number of regional lymph nodes involved: 1

Number of regional lymph nodes examined: 23

Distant Metastasis (pM): Not applicable

Margins: Negative for invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.1cm

Closest margin: radial

Treatment Effect: No prior treatment

Angiolymphatic Invasion: Absent

Perineural Invasion: Present

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

Tumor size: 2.5 cm

[page 3 of 3]
Histologic type: Adenocarcinoma, ductal type

Histologic grade: Moderately differentiated

Tumor extent: Other - Peripancreatic soft tissues

Lymph nodes: 1/23 positive for metastasis (Regional 1/23)

Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 78ef7b13-f809-4717-b05b-fec8336edea2 (TCGA-FB-AAQ3.15FE46F1-194A-4799-8C77-A3FA23CC5D96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).